Surgical pathology report (de-identified scan), TCGA case TCGA-HE-A5NI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-A5NI-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	papillary renal carcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	left kidney
Tumour Size (cm)	4
Histology	papillary renal carcinoma
Grade/Differentiation	III
Pathological T	T1a
Pathological N	NX
Clinical M	M0
Histology Comments	Fuhrman nuclear grade 3/4

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

IOD-03
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS C64.9
2/11/13

Source: NCI Genomic Data Commons file 4ef5d4c7-c822-4fcd-a014-a3bd771b39ac (TCGA-HE-A5NI.102D45C0-82F2-451E-B7DA-AA30F31FC98C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).